CGCI case HTMCP-01-06-00175 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/93ba4fb9-b545-4d71-9ff7-05b775fdfdc1

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 35 years; Vital status: Dead; Days to death: 583 days (1.6 years).

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: primary; Year of diagnosis: 2014; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 583 days (1.6 years); Ann Arbor extranodal involvement: Yes; Sites of involvement: Pleura.
   Pathology details: Lymph node involved site: Submandibular.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Splenic.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Pathology details: Lymph node involved site: Axillary; Tumor largest dimension diameter: 10 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP-21; Days to treatment start: 23 days; Days to treatment end: 293 days; Number of cycles: 6; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 23 days; Days to treatment end: 293 days; Number of cycles: 6; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Progressive Disease; Regimen or line of therapy: GDP; Days to treatment start: 393 days (1.1 years); Days to treatment end: 479 days (1.3 years); Number of cycles: 4; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Dexamethasone + Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 393 days (1.1 years); Days to treatment end: 479 days (1.3 years); Number of cycles: 4; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Progressive Disease; Regimen or line of therapy: DHAP; Days to treatment start: 508 days (1.4 years); Days to treatment end: 536 days (1.5 years); Number of cycles: 2; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Cytarabine + Dexamethasone; Initial disease status: Progressive Disease; Days to treatment start: 508 days (1.4 years); Days to treatment end: 536 days (1.5 years); Number of cycles: 2; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 326 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Spleen; Days to recurrence: 326 days.
- Days to follow up: 389 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 583 days (1.6 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day -1.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Lactate Dehydrogenase 473 [Blood test normal range upper: 298].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day -1: Comorbidities: HIV/AIDS.
- Day -1: Risk factors: HIV/AIDS.
- Day 0: Weight: 52 kg; Height: 159 cm; BMI: 20.6; CD4 count: 74; Haart treatment indicator: No; HIV viral load: 142506.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-01-06-00175-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-06-00175-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-06-00175-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Tobacco smoking history indicator: 1; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical; Lymph node involvement site: para-aortic.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Pleura/Pleural Effusion.
- Primary pathology: Extranodal site involvement: 1; Method initial path diagnosis: Biopsy (all types); Lymph nodes examined: No.
- Tests performed: LDH level: 473.
- Follow-up form 1: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment 1: Therapy regimen: Progression; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: DHAP(CISPLATIN,CYTARABINE,DEXAMETHASONE); Pharma adjuvant cycles count: 2; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharma adjuvant cycles count: 6.
- Treatments, Treatment 3: Therapy regimen: Progression; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: GDP(Gemcitabine,Dexamethasone,cisplatin); Pharma adjuvant cycles count: 4; Treatment best response: Clinical Progressive Disease.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-06-00175-01A-01R-4427:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-06-00175-01A-01D-4427:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-06-00175-10A-01D-4427:
- % tumour top: 0
- % tumour bottom: 0
